Somatic mutation profile of tumor specimen MBCProject_6215_T2_WES (aliquot MBCProject_6215_T2_WES_1) from CMI case MBCProject_6215, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 43.2 years (15,764 days).
Specimen MBCProject_6215_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73799da5-5ee8-466e-b24d-c081bd8a8da3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_6215_SALIVA (Saliva), aliquot MBCProject_6215_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3661380-462f-49ca-96f2-027d11bd7a9f

The open-access MAF lists 26 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 5, Frame Shift Del 2, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1636C>A p.Q546K | Missense Mutation (SNP) | VAF 46/212 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 72/345 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARAP3 | c.3155C>T p.T1052M | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767928406, COSV104381697; called by muse, mutect2, varscan2
- FAM47A | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.052); catalogued as rs201264239, COSV60497671; called by muse, mutect2, varscan2
- FERMT2 | c.694A>G p.I232V | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.017); catalogued as rs1187223577; called by muse, mutect2, varscan2
- NIBAN3 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as rs1299930592; called by muse, mutect2
- RELN | c.6473C>T p.T2158I | Missense Mutation (SNP) | VAF 31/384 reads (8%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.935); catalogued as COSV100633617; called by muse, mutect2
- RYR3 | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.89); catalogued as rs757325144, COSV66782669; called by muse, mutect2
- XRN1 | c.3130C>T p.R1044C | Missense Mutation (SNP) | VAF 19/211 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53813580; called by muse, mutect2
- AKAP3 | c.623G>T p.S208I | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- ANKRD20A1 | c.531G>T p.K177N | Missense Mutation (SNP) | VAF 21/288 reads (7%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.824); called by muse, mutect2
- CNTN2 | c.581T>G p.I194S | Missense Mutation (SNP) | VAF 72/310 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CS | c.1117A>T p.M373L | Missense Mutation (SNP) | VAF 84/423 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EGFL6 | c.556C>A p.P186T | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- MKNK2 | c.1073G>A p.S358N | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- NCOR1 | c.3379del p.Q1127Nfs*5 | Frame Shift Del (DEL) | VAF 34/136 reads (25%) | called by mutect2, pindel, varscan2
- RPS27A | c.74del p.N25Mfs*2 | Frame Shift Del (DEL) | VAF 58/499 reads (12%) | called by mutect2, pindel, varscan2
- SMCHD1 | c.999G>C p.Q333H | Missense Mutation (SNP) | VAF 43/264 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIP12 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- CUL1 | c.216G>A p.S72= | Silent (SNP) | VAF 11/191 reads (6%) | catalogued as rs894830474; called by muse, mutect2
- DPEP3 | c.504T>C p.C168= | Silent (SNP) | VAF 34/155 reads (22%) | called by muse, mutect2, varscan2
- GABRQ | c.456C>T p.F152= | Silent (SNP) | VAF 24/278 reads (9%) | catalogued as rs781952537, COSV64782288; called by muse, mutect2
- MYO10 | c.3039C>T p.H1013= | Silent (SNP) | VAF 11/121 reads (9%) | catalogued as rs370548236; called by muse, mutect2
- PLD5 | c.93A>G p.P31= | Silent (SNP) | VAF 34/141 reads (24%) | called by muse, mutect2, varscan2
- KREMEN2 | c.1178+75G>C | Intron (SNP) | VAF 18/99 reads (18%) | called by muse, mutect2, varscan2
- MCM8 | c.*362T>A | 3'UTR (SNP) | VAF 6/96 reads (6%) | catalogued as rs905154775; called by muse, mutect2
